CCDI case PBBSPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/52b84965-4131-433b-938b-3e68a4b1f189

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,259 days).

Biospecimens (4 samples)
- Samples 0DFRU5, 0DFRU6 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRU7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFUJK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
